TARGET case TARGET-00-SJNORM054698 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/3cf40e0c-e428-472e-ba67-ad085403196d

Biospecimens (3 samples)
- Samples TARGET-00-SJNORM054698-14A.1, TARGET-00-SJNORM054698-14A.2, TARGET-00-SJNORM054698-14A.3 (3 with the same recorded description): Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
